Somatic mutation profile of tumor specimen TCGA-ET-A3BV-01A (aliquot TCGA-ET-A3BV-01A-11D-A19J-08) from TCGA case TCGA-ET-A3BV, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 47.8 years (17,441 days).
Specimen TCGA-ET-A3BV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4460185d-2a35-454a-97e3-00c7874a91c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3BV-10A (Blood Derived Normal), aliquot TCGA-ET-A3BV-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f17fa367-e371-44ac-8b8f-975bc05e3346

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, In Frame Del 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARHGAP26 | c.1115A>C p.N372T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV50836051; called by muse, mutect2, varscan2
- CDC42 | c.188A>T p.D63V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59662284; called by muse, varscan2
- CTDP1 | c.1336A>G p.T446A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50006578; called by muse, mutect2
- DLG5 | c.2573C>A p.P858Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV64948991; called by muse, mutect2
- IMPDH2 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV58708518; called by muse, mutect2
- MGAT5B | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs749963645, COSV56933211; called by muse, mutect2, varscan2
- MTBP | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as COSV59964831; called by muse, mutect2, varscan2
- PTPN21 | c.2398G>C p.D800H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60850386; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1045C>G p.L349V | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52864312; called by muse, mutect2, varscan2
- SPAG9 | c.3586G>C p.E1196Q (on ENST00000262013 / NM_001130528.3; = p.E1182Q on NM_003971.6) | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV56239935; called by muse, mutect2
- SRCAP | c.6364G>A p.G2122S | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV52677310; called by muse, mutect2
- THEG | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV61074429; called by muse, mutect2, varscan2
- TRIP11 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs947598699, COSV50940854; called by muse, mutect2
- VMO1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs147226483; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.162_173del p.I55_A58del | In Frame Del (DEL) | VAF 16/73 reads (22%) | called by mutect2, pindel, varscan2
- SETD2 | c.6642del p.E2215Nfs*33 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- CFAP20DC | c.1575C>A p.G525= (on ENST00000482387 / NM_001351530.2; = p.G400= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs148755922, COSV55924233; called by muse, mutect2, varscan2
- IGFN1 | c.1404G>A p.Q468= (on ENST00000295591 / NM_001367841.1; = p.Q2925= on NM_001164586.2) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV55179184, COSV99812189; called by muse, mutect2, varscan2
- OTOP3 | c.531C>T p.D177= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV60914215; called by muse, mutect2
- SPTBN2 | c.1914G>A p.E638= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs367863277; called by muse, mutect2, varscan2
- TFPI | c.708T>C p.N236= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV51903838; called by muse, mutect2, varscan2
- UBN1 | c.2088T>G p.P696= | Silent (SNP) | VAF 32/330 reads (10%) | catalogued as COSV52170598; called by muse, mutect2
- METTL1 | c.-21G>C | 5'UTR (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
